Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOD, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AAOD-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY TISSUE REPORT

Name: _____

- Specimen Source: RIGHT TESTICLE AND TUBE
- Gross Exam Date:
- Physician:

Pager No.: _____

ADDENDUM REPORT FOR

The choriocarcinoma is strongly positive by HCG and CAM5.2, while the seminoma and the intratubular germ cell neoplasia are positive for c-Kit. The seminoma is negative for CAM5.2 immunostains. The CD-30 is negative.

These findings support the diagnoses:

- 1) MIXED GERM CELL TUMOR WITH SEMINOMA (80%), CHORIOCARCINOMA (20%)
right radical orchiectomy (see note)
- 2) TUMOR MEASURES 3 CM WITH AREAS OF NECROSIS AND HEMORRHAGE
- 3) TUMOR LIMITED TO TESTES
- 4) NO INVASION OF EPIDIDYMIS NOTED
- 5) LYMPHOVASCULAR INVASION NOTED
- 6) SURGICAL MARGINS FREE OF TUMOR
- 7) INTRATUBULAR GERM CELL NEOPLASIA
- 8) SEMINIFEROUS TUBULES WITH EVIDENCE OF SPERMATOGENESIS AND ATROPHY

ICD-O-3

Mixed germ cell tumor 9085/3

Site R Testis NOS C62.9

MO 3/21/14

IN FT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 4]
Name:

Operative Procedure: RIGHT RADICAL ORCHIECTOMY

- Specimen Source: RIGHT TESTICLE AND TUBE
- Gross Exam Date:
- Physician:

Pager No.:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

- 9) MIXED GERM CELL TUMOR WITH SEMINOMA (80%), CHORIOCARCINOMA (20%)
right radical orchiectomy (see note)
- 10) TUMOR MEASURES 3 CM WITH AREAS OF NECROSIS AND HEMORRHAGE
- 11) TUMOR LIMITED TO TESTES
- 12) NO INVASION OF EPIDIDYMIS NOTED

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

PAGE 2

[page 3 of 4]
Name:

Operative Procedure: RIGHT RADICAL ORCHIECTOMY

- Specimen Source: RIGHT TESTICLE AND TUBE

- Gross Exam Date:

- Physician:

Pager No.:

13) LYMPHOVASCULAR INVASION NOTED

14) SURGICAL MARGINS FREE OF TUMOR

15) INTRATUBULAR GERM CELL NEOPLASIA

16) SEMINIFEROUS TUBULES WITH EVIDENCE OF SPERMATOGENESIS AND ATROPHY

Note: PT2NXMX. Special stains pending.
at

notified on

GROSS DESCRIPTION:

The specimen is received in one part, unfixed, labeled with the patient's name, and "right testicle and tube." It consists of a 60-gram orchiectomy specimen including 4.5 x 3.5 x 3-cm testis, 3 x 0.7 x 0.4-cm epididymis, and 10 cm in length and 1.5 cm in diameter spermatic cord. Right next to the epididymis there is a 3 x 1.8 x 1.8-cm white-tan to pink-tan, fleshy, well-circumscribed mass with focal areas of hemorrhage and necrosis. There is no gross involvement of the tunica albuginea. The remaining testicular parenchyma is grossly unremarkable. The spermatic cord consists of vas deferens, arteries, and veins, and is unremarkable. R8.

Cassettes:

- 1 to 2. Tumor.
3. Tumor and tunica vaginalis.
4. Tumor and epididymis.
5. Tumor and adjacent testis.
6. Spermatic cord resection margin.

IN FT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

PAGE 3

[page 4 of 4]
Name:

Sex:

Operative Procedure: RIGHT RADICAL ORCHIECTOMY

- Specimen Source: RIGHT TESTICLE AND TUBE

- Gross Exam Date:

- Physician:

Pager No.:

7. Spermatic cord midportion.

8. Spermatic cord peritesticular portion.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

PAGE 4

Critere	AN 1/21/14	Yes	No

Source: NCI Genomic Data Commons file 314ed2f3-98ac-4752-9d9a-2a616d5da9b4 (TCGA-XE-AAOD.B84B10F5-4CB6-4BB6-AFF7-CEE6603380E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).